Surgical pathology report (de-identified scan), TCGA case TCGA-61-1733, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1733-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY -

HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING THE OMENTUM (see comment).

PART 2: UTERUS AND CERVIX WITH BILATERAL ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY, BILATERAL SALPINGO-OOPHORECTOMY -

- A. HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING BILATERAL OVARIES, BILATERAL PARATUBAL TISSUE AND UTERINE SEROSA.
- B. ATROPHIC ENDOMETRIUM.
- C. CERVIX IS NEGATIVE FOR TUMOR.
- D. BILATERAL BENIGN TUBAL MUCOSA.

PART 3: CUL-DE-SAC, TUMOR DEBULKING -

HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING FIBROADIPOSE TISSUE.

PART 4: COLON, SIGMOID, RESECTION -

- A. HIGH-GRADE PAPILLARY SEROUS CARCINOMA WITH TRANSMURAL INVOLVEMENT OF THE BOWE WALL.
- B. THE TUMOR IS ALSO IDENTIFIED WITHIN THE LYMPHOVASCULAR SPACES.
- C. THE COLONIC MUCOSAL MARGINS ARE NEGATIVE.

PART 5: "LIVER NODULE", EXCISION -

- A. HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING FIBROADIPOSE TISSUE.
- B. NO LIVER PARENCHYMA IDENTIFIED.

PART 6: COLON, RESECTION -

- A. HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING BOWEL WALL.
- B. THE TUMOR IS IDENTIFIED WITHIN THE LYMPHOVASCULAR SPACES.
- C. THE COLONIC MUCOSAL MARGINS ARE NEGATIVE.
- D. THE TUMOR IS ALSO IDENTIFIED IN DETACHED PERICOLONIC TISSUE.

PART 7: OMENTUM, SUB-GASTRIC, OMENTECTOMY -

HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING FIBROADIPOSE TISSUE.

PART 8: COLON, LEFT, RESECTION -

BENIGN COLONIC MUCOSA AND WALL.

PART 9: PARACOLIC GUTTER, RIGHT, TUMOR DEBULKING-

HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING FIBROADIPOSE TISSUE.

PART 10: STOMACH, LESSER CURVATURE, TUMOR DEBULKING -

HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING FIBROADIPOSE TISSUE.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 7 cm
TUMOR TYPE:	Papillary serous carcinoma
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Intact
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Uterus, Fallopian Tubes, Omentum, Peritoneal metastasis beyond the pelvis
SURFACE IMPLANT SIZE:	> 2 cm.
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 0
T STAGE, PATHOLOGIC:	pT3c
N STAGE, PATHOLOGIC:	pNX
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	IIIC
Comment:	The bulk of the tumor is present within the omentum (45 cm) and likely represents a peritoneal primary. The tumor in the right ovary measured 7 cm and in the left ovary measured 6 cm.

Source: NCI Genomic Data Commons file a88f9eb7-6bfc-4e24-823a-df4c8c4991c4 (TCGA-61-1733.BC4E6E92-D716-4AB3-8459-4F339CAECFFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).